Surgical pathology report (de-identified scan), TCGA case TCGA-85-6175, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-6175-01A (Primary Tumor).

[REDACTED]

Asterand Case ID	OpenClinica Subject ID	Formatted Path Report	BCR
[REDACTED]	[REDACTED]	LUNG TISSUE CHECKLIST Specimen type: Pneumonectomy Tumor site: Lung Tumor size: 10 x 10 x 4 cm Histologic type: Squamous cell carcinoma Histologic grade: Well differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: Not specified Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None	[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 3c278e03-065e-4483-890f-07bbbf85d08a (TCGA-85-6175.616D5519-7F8D-4EB0-B78A-6A90C84616FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).